Somatic mutation profile of tumor specimen TCGA-ZF-A9RC-01A (aliquot TCGA-ZF-A9RC-01A-11D-A38G-08) from TCGA case TCGA-ZF-A9RC, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 77.4 years (28,275 days).
Specimen TCGA-ZF-A9RC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 555b3048-4ede-4453-8032-103c9be8a4a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-A9RC-10A (Blood Derived Normal), aliquot TCGA-ZF-A9RC-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b71a03df-8099-41c8-ac18-e6c17a5d3383

The open-access MAF lists 1,061 somatic variants for this specimen: 730 protein-altering or splice-affecting, 311 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 647, Silent 311, Nonsense Mutation 48, Splice Site 13, Intron 11, Frame Shift Del 11, Splice Region 5, RNA 4, Frame Shift Ins 3, 3'Flank 3, Translation Start Site 2, 5'UTR 1.

Variants (750 of 1,061; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 19/115 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs950730453, COSV54073436, COSV54083862; called by muse, mutect2, varscan2
- ERCC2 | c.41A>G p.Y14C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55540131; called by muse, mutect2, varscan2
- GDAP1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs104894076, CM020375, COSV55186078; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV64674465; called by muse, mutect2, varscan2
- ABCB5 | c.1355T>C p.I452T (on ENST00000404938 / NM_001163941.2; = p.I7T on NM_178559.6) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs781458217, COSV51712199; called by muse, mutect2, varscan2
- AC068580.4 | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.936); catalogued as COSV52588646; called by muse, mutect2, varscan2
- ACBD6 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62574137; called by muse, mutect2, varscan2
- ACSS3 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV54085632, COSV54097587; called by muse, mutect2, varscan2
- ACTG1 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59510803; called by muse, mutect2, varscan2
- ACTR8 | c.1642C>T p.Q548* | Nonsense Mutation (SNP) | VAF 25/140 reads (18%) | catalogued as rs949244723, COSV99213746, COSV99213948; called by muse, mutect2, varscan2
- ADAM28 | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs200511993, COSV56101695; called by muse, mutect2, varscan2
- ADAMTS12 | c.1649C>T p.P550L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs1035390471, COSV61266070; called by muse, mutect2, varscan2
- ADCY2 | c.1872-1G>C p.X624_splice | Splice Site (SNP) | VAF 21/204 reads (10%) | catalogued as COSV57878890; called by muse, mutect2, varscan2
- ADGRD1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.258); catalogued as COSV55448276, COSV55449891; called by muse, mutect2, varscan2
- ADNP | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.156); catalogued as COSV62425885; called by muse, mutect2, varscan2
- AEBP1 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV56258580; called by mutect2, varscan2
- AFTPH | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV53215978; called by muse, mutect2
- AGK | c.976-1G>C p.X326_splice | Splice Site (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100814561, COSV62594884; called by muse, mutect2, varscan2
- AKAP8 | c.1392C>G p.F464L | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.992); catalogued as rs963109568, COSV54103118; called by muse, varscan2
- AKAP9 | c.5806C>T p.H1936Y (on ENST00000359028; = p.H1904Y on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.247); catalogued as COSV100663491, COSV62349396; called by muse, mutect2, varscan2
- AL669918.1 | c.1933-1G>A p.X645_splice | Splice Site (SNP) | VAF 5/40 reads (13%) | catalogued as COSV66503082; called by muse, mutect2, varscan2
- ALK | c.3413T>A p.M1138K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV66573150; called by muse, mutect2
- ALPL | c.1375G>T p.V459L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs1054159992, CM045929, HM971620, COSV66376347; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMDHD1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.152); catalogued as rs773780026, COSV57139216; called by muse, mutect2, varscan2
- AMOTL2 | c.1955G>C p.R652T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV51439529, COSV51441756; called by muse, mutect2, varscan2
- ANKRD26 | c.4311G>A p.M1437I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as COSV101063098, COSV65776183; called by muse, mutect2, varscan2
- ANKRD29 | c.833T>G p.L278R | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV52426419; called by muse, mutect2, varscan2
- ANLN | c.3122A>T p.Q1041L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.316); catalogued as COSV56077200; called by muse, mutect2, varscan2
- AP5M1 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV55105649, COSV55106398; called by muse, mutect2
- APOBEC3D | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.039); catalogued as rs773998723, COSV53327612, COSV99328992; called by muse, mutect2
- APPBP2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.678); catalogued as COSV50027336, COSV99319879; called by muse, varscan2
- AQP5 | c.531C>G p.I177M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.716); catalogued as rs1400711542, COSV53311336; called by muse, mutect2, varscan2
- AR | c.2364G>C p.M788I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as CM102210, CM102211, COSV65958407; called by muse, mutect2, varscan2
- ARHGAP19 | c.1141C>T p.H381Y | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV57393540; called by muse, mutect2, varscan2
- ARHGAP32 | c.1874G>A p.G625E (on ENST00000310343 / NM_001378025.1; = p.G276E on NM_014715.4) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV59850016; called by muse, mutect2, varscan2
- ARID1A | c.4813C>T p.P1605S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV61376332, COSV61380181; called by muse, mutect2, varscan2
- ARMCX2 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV57530454; called by muse, mutect2, varscan2
- ARSJ | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 33/93 reads (35%) | catalogued as COSV100192793; called by muse, mutect2, varscan2
- ASMTL | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 190/542 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV67244011; called by muse, mutect2
- ASMTL | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 193/551 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as rs780461596, COSV67244021; called by muse, mutect2
- ASPH | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.755); catalogued as rs1336198288, COSV100727369, COSV62859787; called by muse, mutect2, varscan2
- ASTE1 | c.1213G>T p.V405L | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV53909023; called by muse, mutect2
- ASXL2 | c.3643C>T p.H1215Y | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs762832344, COSV55460653; called by muse, mutect2, varscan2
- ATE1 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 76/154 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56437695; called by muse, mutect2, varscan2
- ATF7IP | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.079); catalogued as rs150179759, COSV53767250, COSV53772632; called by muse, mutect2, varscan2
- ATG14 | c.477A>C p.Q159H | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV55956968; called by muse, mutect2, varscan2
- ATM | c.5839T>C p.S1947P | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV53751024; called by muse, mutect2, varscan2
- ATP12A | c.1174A>G p.K392E | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200648050, COSV54518117, COSV54523163; called by muse, mutect2, varscan2
- ATP5F1B | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV56261260; called by muse, mutect2, varscan2
- ATP5MC3 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as COSV99507162; called by muse, mutect2, varscan2
- AXIN2 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV61058222; called by muse, mutect2, varscan2
- B4GALT1 | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65707689, COSV65708259; called by muse, mutect2, varscan2
- BAMBI | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs749500911, COSV65003106; called by muse, mutect2, varscan2
- BARX2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.243); catalogued as COSV55650946; called by muse, mutect2, varscan2
- BAZ1A | c.2902C>T p.Q968* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as COSV100701173; called by muse, mutect2, varscan2
- BIRC6 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101428401; called by muse, mutect2
- BIRC6 | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.135); catalogued as COSV101428402; called by muse, mutect2
- BIRC6 | c.5107C>T p.L1703F | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as rs567218300, COSV70197020, COSV70201078; called by mutect2, varscan2
- BMP5 | c.1237C>A p.H413N | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV63702682, COSV63703534; called by muse, mutect2, varscan2
- BRCA2 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as rs772342691, CM136513, COSV66454084, COSV66455729; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRINP2 | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64178199; called by muse, mutect2, varscan2
- BRINP3 | c.1624T>C p.Y542H | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.969); catalogued as COSV66528033; called by muse, mutect2
- BSN | c.11149C>A p.H3717N | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56520824; called by muse, mutect2, varscan2
- BTN2A2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV61857751; called by muse, mutect2, varscan2
- C15orf40 | c.439A>G p.K147E | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV58449941; called by muse, mutect2, varscan2
- C22orf42 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.851); catalogued as COSV66076162; called by muse, mutect2, varscan2
- C3orf38 | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs1284906704, COSV59628340; called by muse, mutect2, varscan2
- C3orf70 | c.53T>G p.L18R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.304); catalogued as COSV58588571; called by muse, mutect2, varscan2
- C9orf50 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs1388746183, COSV65252601; called by muse, mutect2, varscan2
- CAGE1 | c.919G>A p.E307K (on ENST00000512086; = p.E171K on NM_205864.3) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV57078423; called by muse, mutect2
- CAPZA1 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.983); catalogued as rs377339360, COSV54146282; called by muse, mutect2, varscan2
- CASP8 | c.1303C>T p.R435* (on ENST00000432109 / NM_033355.3; = p.R452* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | catalogued as rs1368296717, COSV51844657; called by muse, mutect2, varscan2
- CBFA2T2 | c.125G>A p.R42K | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV60074447; called by muse, mutect2, varscan2
- CBFA2T2 | c.287C>G p.S96C | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV60074462; called by muse, mutect2
- CCN1 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101486131; called by muse, mutect2
- CCN1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.574); catalogued as COSV71704373; called by muse, mutect2, varscan2
- CCNF | c.591C>G p.F197L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.385); catalogued as rs762067213, COSV53540484, COSV53540806; called by muse, mutect2, varscan2
- CCNYL1 | c.1036G>A p.D346N (on ENST00000295414 / NM_001330218.2; = p.D276N on NM_152523.2) | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54940818; called by muse, mutect2, varscan2
- CCP110 | c.286A>G p.N96D | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs766354418, COSV66817174; called by muse, mutect2, varscan2
- CD109 | c.2922C>G p.F974L | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1357802150, COSV54651469, COSV54652271; called by muse, mutect2, varscan2
- CD109 | c.3154A>C p.I1052L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV54651479; called by muse, mutect2, varscan2
- CD1A | c.82C>T p.H28Y | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as COSV56862388; called by muse, mutect2, varscan2
- CD200 | c.655T>C p.S219P (on ENST00000473539 / NM_001004196.3; = p.S194P on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV59863571; called by muse, mutect2, varscan2
- CD46 | c.731A>C p.K244T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as COSV59733941; called by muse, mutect2, varscan2
- CD96 | c.1053G>C p.L351F (on ENST00000283285 / NM_198196.3; = p.L335F on NM_005816.5) | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV51917869; called by muse, mutect2, varscan2
- CDH26 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.616); catalogued as COSV54848350; called by muse, mutect2, varscan2
- CDH6 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV54072056; called by muse, mutect2, varscan2
- CDH6 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.398); catalogued as COSV54072066; called by muse, mutect2, varscan2
- CDK8 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV67421230; called by muse, mutect2, varscan2
- CENPF | c.7069C>G p.L2357V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.426); catalogued as COSV65275816; called by muse, mutect2, varscan2
- CENPH | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.083); catalogued as COSV51585031; called by muse, mutect2, varscan2
- CENPT | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV54650385; called by muse, mutect2
- CEP104 | c.1275G>C p.L425F | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as COSV65517979, COSV65520184; called by muse, mutect2
- CEP250 | c.5473G>A p.E1825K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.164); catalogued as COSV61171000; called by muse, mutect2, varscan2
- CFAP94 | c.1345G>A p.E449K (on ENST00000320267 / NM_001352064.2; = p.E455K on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as COSV57233361; called by muse, mutect2, varscan2
- CFTR | c.2960T>C p.L987P | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50063139; called by muse, mutect2
- CHAF1B | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 42/378 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV58440398; called by muse, mutect2, varscan2
- CHDH | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV59458216; called by muse, mutect2, varscan2
- CHRDL2 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.804); catalogued as COSV99733856; called by muse, mutect2
- CIAO1 | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 11/118 reads (9%) | catalogued as rs1158535572, COSV99720448; called by muse, mutect2
- CLASP2 | c.4225C>T p.Q1409* (on ENST00000359576; = p.Q1408* on NM_015097.3 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100223647; called by muse, mutect2, varscan2
- CLCA4 | c.982C>G p.Q328E | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV55368830; called by muse, mutect2, varscan2
- CLCN5 | c.1100C>G p.T367S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV56584879; called by muse, mutect2, varscan2
- CLK2 | c.928G>A p.E310K (on ENST00000368361 / NM_001294339.2; = p.E309K on NM_003993.4) | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV100226807, COSV56945955; called by muse, mutect2
- CLMN | c.2701C>T p.P901S | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as COSV54183391; called by muse, mutect2
- CLNK | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV57016746; called by muse, mutect2, varscan2
- CMYA5 | c.6001G>A p.E2001K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as rs1171231451, COSV71406679; called by muse, mutect2, varscan2
- CNKSR1 | c.1921G>A p.E641K (on ENST00000374253 / NM_001297647.2; = p.E634K on NM_006314.3) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV58793575; called by muse, mutect2, varscan2
- CNKSR2 | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs781500401, COSV54258896; called by muse, mutect2, varscan2
- CNTN4 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.373); catalogued as COSV61875049; called by muse, mutect2, varscan2
- CNTRL | c.5620G>A p.A1874T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1341870106, COSV53048747; called by muse, mutect2, varscan2
- COG1 | c.701G>C p.R234T | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55429138, COSV55430332; called by muse, mutect2, varscan2
- COL24A1 | c.4649A>C p.N1550T | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV65308207; called by muse, mutect2, varscan2
- COL24A1 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV65308209; called by muse, mutect2, varscan2
- COP1 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.956); catalogued as COSV58169494; called by muse, mutect2, varscan2
- COPA | c.1786G>T p.E596* | Nonsense Mutation (SNP) | VAF 37/108 reads (34%) | catalogued as COSV99615964; called by muse, mutect2, varscan2
- COPA | c.874G>T p.D292Y | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54104225; called by muse, mutect2, varscan2
- COPG1 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59114650; called by muse, mutect2, varscan2
- CPB1 | c.1065C>T p.I355= | Splice Region (SNP) | VAF 5/56 reads (9%) | catalogued as COSV51574357; called by muse, mutect2
- CPD | c.2513G>A p.G838E | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56713757; called by muse, mutect2, varscan2
- CPED1 | c.2923A>G p.R975G | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV60004940; called by mutect2, varscan2
- CPLANE1 | c.7879G>A p.V2627I | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0.011); catalogued as rs1278821839, COSV57063258; called by muse, mutect2, varscan2
- CRB1 | c.3448C>A p.H1150N | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.497); catalogued as rs372272372; called by muse, mutect2, varscan2
- CROT | c.1762G>C p.D588H | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55936800; called by muse, mutect2
- CSE1L | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.583); catalogued as rs1416484455, COSV53702606, COSV53705669; called by muse, mutect2
- CSGALNACT2 | c.338A>C p.K113T | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.27); catalogued as COSV65675867; called by muse, mutect2, varscan2
- CSMD2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.11); catalogued as COSV53923298; called by muse, mutect2, varscan2
- CTNNBL1 | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as COSV63745368; called by muse, mutect2, varscan2
- CTSB | c.794G>C p.G265A | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61540849; called by muse, mutect2, varscan2
- CYB5R1 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as rs972504280, COSV65917020; called by muse, mutect2, varscan2
- CYBRD1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs764578336, COSV58426296; called by muse, mutect2, varscan2
- CYGB | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs749158794, COSV99506165; called by muse, mutect2
- CYP2J2 | c.343C>G p.P115A | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.344); catalogued as COSV64606358; called by muse, mutect2, varscan2
- DDHD2 | c.1580T>G p.F527C | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs777959872, COSV68158103; called by muse, mutect2, varscan2
- DDX5 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56749825; called by muse, mutect2
- DDX60 | c.5075A>T p.D1692V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67097326; called by muse, mutect2, varscan2
- DEDD | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63502045; called by muse, mutect2, varscan2
- DEFB124 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100478846; called by muse, mutect2, varscan2
- DENND4C | c.2384C>G p.P795R | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV66822423; called by muse, mutect2, varscan2
- DENND4C | c.3805G>A p.E1269K (on ENST00000434457 / NM_001330640.2; = p.E1220K on NM_017925.7) | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as COSV63009102; called by muse, mutect2, varscan2
- DENND5A | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV60234793; called by muse, mutect2, varscan2
- DGKH | c.1914T>G p.V638= | Splice Region (SNP) | VAF 8/124 reads (6%) | catalogued as COSV54934266; called by muse, mutect2
- DHX32 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52940146; called by muse, mutect2, varscan2
- DHX35 | c.871G>T p.V291L | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV52671279; called by muse, mutect2, varscan2
- DHX9 | c.3402G>A p.M1134I | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV62360207; called by muse, mutect2, varscan2
- DIO3 | c.202C>G p.R68G | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63773880, COSV63774700; called by muse, mutect2, varscan2
- DIPK2A | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as rs756937184, COSV59857695; called by muse, mutect2
- DLD | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV52738461; called by muse, mutect2
- DLG3 | c.2119C>T p.Q707* (on ENST00000374360 / NM_021120.4; = p.Q402* on NM_020730.3) | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99529735; called by muse, mutect2, varscan2
- DLGAP1 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as rs1215741136, COSV100231847; called by muse, mutect2, varscan2
- DMXL2 | c.8261G>C p.G2754A | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV51848756, COSV99196356; called by muse, mutect2, varscan2
- DNAH10 | c.11525C>A p.S3842* (on ENST00000409039; = p.S3781* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV101292340; called by muse, mutect2, varscan2
- DNAH17 | c.5698G>A p.E1900K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101101544, COSV67756840; called by muse, mutect2, varscan2
- DNAH2 | c.2386C>A p.H796N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV66721033; called by muse, mutect2, varscan2
- DNAH5 | c.9968T>A p.M3323K | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV54232806; called by muse, mutect2
- DNAJA1 | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as rs748492377, COSV58310636; called by muse, mutect2, varscan2
- DNAJB11 | c.761G>A p.R254K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as COSV54002927; called by muse, mutect2, varscan2
- DNAJB9 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.656); catalogued as COSV99974520; called by muse, mutect2
- DNAJC6 | c.614C>A p.S205* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as rs1261374566, COSV99675108; called by muse, mutect2, varscan2
- DOCK11 | c.4770G>A p.M1590I | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52241306; called by muse, mutect2, varscan2
- DOLK | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58281236; called by muse, mutect2, varscan2
- DOP1A | c.5083C>T p.Q1695* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as COSV99382193; called by muse, mutect2, varscan2
- DPH2 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1306957426, COSV52543828; called by muse, mutect2, varscan2
- DSP | c.5818G>A p.D1940N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV65793428; called by muse, mutect2, varscan2
- DSPP | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.038); catalogued as COSV99217512; called by muse, mutect2
- DTX4 | c.1784A>G p.N595S | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.251); catalogued as COSV99915568; called by muse, mutect2
- DUSP1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.983); catalogued as COSV53320412; called by muse, mutect2, varscan2
- DYNC1H1 | c.7906G>A p.D2636N | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64138154; called by muse, mutect2, varscan2
- DYNC1H1 | c.10859G>A p.R3620K | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.705); catalogued as COSV64137872; called by muse, varscan2
- EFCAB14 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100905632; called by muse, mutect2
- EFTUD2 | c.2099T>C p.I700T | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53655830; called by muse, mutect2, varscan2
- EHMT2 | c.3572G>A p.R1191H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1181533264, COSV57667719; called by muse, mutect2, varscan2
- EID1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV60111468; called by muse, mutect2, varscan2
- EIF2S3 | c.1304C>T p.T435I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV53407039; called by muse, mutect2, varscan2
- EIF3K | c.500-1G>A p.X167_splice | Splice Site (SNP) | VAF 9/41 reads (22%) | catalogued as COSV50264233; called by muse, mutect2, varscan2
- ELAPOR1 | c.2396A>G p.Y799C | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV64040629; called by muse, mutect2, varscan2
- ELMO3 | c.1426G>C p.E476Q (on ENST00000652269; = p.E423Q on NM_024712.5) | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58527496; called by muse, mutect2, varscan2
- ELP1 | c.1760C>A p.S587Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as COSV65898276; called by muse, mutect2, varscan2
- EML4 | c.1031G>C p.R344T | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59300003; called by muse, mutect2, varscan2
- ENAH | c.1707A>C p.E569D (on ENST00000366844 / NM_001008493.3; = p.E548D on NM_018212.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52869233; called by muse, mutect2, varscan2
- ENC1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV56630004; called by muse, mutect2, varscan2
- ENPP5 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57909048, COSV57910239; called by muse, mutect2, varscan2
- ENTPD8 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as rs556851035, COSV58162342; called by muse, mutect2, varscan2
- EP300 | c.2113C>G p.R705G | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54335382; called by muse, mutect2, varscan2
- EPHA7 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100992418, COSV100992419; called by muse, mutect2, varscan2
- EPHB4 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs780798389, COSV62269372; called by muse, mutect2, varscan2
- ESF1 | c.1114T>C p.F372L | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52521823; called by muse, mutect2, varscan2
- ESRP1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1162356116, COSV64410496; called by muse, mutect2, varscan2
- ETS2 | c.1390C>T p.Q464* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100711301; called by muse, mutect2
- ETV4 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.043); catalogued as rs776306922, COSV100081499, COSV60043769; called by muse, varscan2
- EXPH5 | c.5120C>G p.S1707* | Nonsense Mutation (SNP) | VAF 11/181 reads (6%) | catalogued as COSV99761761; called by muse, mutect2
- EXTL2 | c.613G>C p.G205R | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64473166; called by muse, mutect2
- EYA3 | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1168341928, COSV65816976; called by muse, mutect2, varscan2
- F9 | c.205T>C p.C69R | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM098269, CM940426, COSV54380902; called by muse, mutect2, varscan2
- FAM117B | c.1588A>C p.K530Q | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV57419867, COSV57420354; called by muse, mutect2, varscan2
- FAM209B | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs192848959, COSV100990949, COSV64915048; called by muse, mutect2, varscan2
- FAM219B | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs768740248, COSV60397049; called by muse, mutect2, varscan2
- FAM221B | c.57C>A p.H19Q | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs1432041234, COSV65074555; called by muse, mutect2, varscan2
- FAM3D | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62558547; called by muse, mutect2, varscan2
- FAM83F | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61000474; called by muse, mutect2, varscan2
- FAM8A1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs1366000323, COSV52580283, COSV52580559; called by muse, mutect2, varscan2
- FAT1 | c.13090G>A p.E4364K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV71674700; called by muse, mutect2, varscan2
- FBN1 | c.2194G>A p.D732N | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.578); catalogued as COSV57320216; called by muse, mutect2, varscan2
- FBXO3 | c.164G>A p.R55K | Missense Mutation (SNP) | VAF 86/337 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.085); catalogued as COSV55766852; called by muse, mutect2, varscan2
- FBXO43 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 136/214 reads (64%) | SIFT tolerated (0.98); PolyPhen benign (0.306); catalogued as COSV101413827, COSV71054426; called by muse, mutect2, varscan2
- FGFR1 | c.1054C>T p.H352Y (on ENST00000447712 / NM_023110.3; = p.H350Y on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV58337022; called by muse, mutect2, varscan2
- FLG | c.10777G>A p.E3593K | Missense Mutation (SNP) | VAF 106/520 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV64243214; called by muse, mutect2, varscan2
- FMO3 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV63006968, COSV63007633; called by muse, mutect2
- FNDC11 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.412); catalogued as COSV100918806; called by muse, mutect2
- FOXE1 | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64300607; called by muse, mutect2, varscan2
- FOXP2 | c.1495A>G p.K499E | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV63487926, COSV63488057; called by muse, mutect2, varscan2
- FOXP4 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV57220823; called by muse, mutect2, varscan2
- FPGS | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV64675785; called by muse, mutect2, varscan2
- FRY | c.3917G>A p.G1306E | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.777); catalogued as COSV66572239; called by muse, mutect2
- FSIP2 | c.19975G>A p.E6659K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as rs778750574, COSV58089440; called by muse, mutect2, varscan2
- FUT5 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.711); catalogued as rs1329828365, COSV53136423; called by muse, mutect2, varscan2
- GABRA3 | c.780A>G p.G260= | Splice Region (SNP) | VAF 4/28 reads (14%) | catalogued as COSV64795489; called by muse, mutect2, varscan2
- GABRB3 | c.993C>G p.F331L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as COSV54669739, COSV54685711; called by muse, mutect2, varscan2
- GART | c.1024A>G p.K342E | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV63113918; called by muse, mutect2, varscan2
- GCC1 | c.18G>A p.M6I | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV50001282; called by muse, mutect2
- GCKR | c.1753A>T p.T585S | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99269166; called by muse, mutect2
- GET4 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.115); catalogued as COSV56214801; called by muse, mutect2, varscan2
- GFPT1 | c.667C>G p.P223A | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.174); catalogued as COSV61948600; called by muse, mutect2
- GLCCI1 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.875); catalogued as COSV56202716; called by muse, mutect2, varscan2
- GLG1 | c.2101C>T p.Q701* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as COSV52669333, COSV99215917; called by muse, mutect2
- GLIPR1L2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57554553; called by muse, mutect2, varscan2
- GMPR | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 98/165 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV52473824; called by muse, mutect2, varscan2
- GNPTAB | c.3559G>A p.E1187K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV73418359; called by muse, mutect2, varscan2
- GOLGA4 | c.1416A>C p.K472N | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62711454; called by muse, mutect2
- GPAA1 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100284100, COSV60155993; called by muse, mutect2
- GPATCH8 | c.2287G>C p.E763Q | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.143); catalogued as COSV59195537; called by muse, mutect2
- GPR37 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100390965; called by muse, mutect2
- GPRASP1 | c.2124C>G p.F708L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV64355874; called by muse, mutect2, varscan2
- GPRIN2 | c.804del p.L270Cfs*7 | Frame Shift Del (DEL) | VAF 15/122 reads (12%) | catalogued as COSV65401321; called by mutect2, pindel, varscan2
- GPX1 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as COSV69042790, COSV69043951; called by muse, mutect2, varscan2
- GRHPR | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV58941225; called by muse, mutect2, varscan2
- GRK5 | c.1279G>C p.D427H | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV64866710; called by muse, mutect2
- GRM8 | c.427A>T p.K143* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV100280928; called by muse, mutect2, varscan2
- GSDMD | c.674C>G p.S225C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV52797499; called by muse, mutect2, varscan2
- GSTM3 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV56662461; called by muse, mutect2
- GTF2I | c.1336T>G p.L446V (on ENST00000573035 / NM_032999.4; = p.L405V on NM_001518.5) | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.058); catalogued as COSV60401871; called by muse, mutect2, varscan2
- GUCY2D | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54696790; called by muse, mutect2
- H2AC13 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1213656988, COSV100704396; called by mutect2, varscan2
- H3C10 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV60797298, COSV60799019; called by muse, mutect2, varscan2
- HAGH | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1335548401, COSV66900021; called by muse, mutect2, varscan2
- HASPIN | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs1176915274, COSV53995553; called by muse, mutect2, varscan2
- HCRTR2 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100904406; called by muse, mutect2, varscan2
- HECTD3 | c.528C>T p.L176= | Splice Region (SNP) | VAF 9/43 reads (21%) | catalogued as rs1414785491, COSV55800851; called by muse, mutect2, varscan2
- HGH1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs370307214; called by muse, mutect2, varscan2
- HK1 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV53860070; called by muse, mutect2, varscan2
- HLTF | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as rs1448725109, COSV59501609; called by muse, mutect2, varscan2
- HMCN1 | c.9233C>T p.S3078F | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54898632, COSV54909710; called by muse, mutect2
- HMCN1 | c.16746G>C p.L5582F | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54909722; called by muse, mutect2, varscan2
- HMGCS2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.633); catalogued as COSV65568253; called by muse, mutect2, varscan2
- HOXA1 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV56066795, COSV99761192; called by muse, mutect2, varscan2
- HOXB6 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.058); catalogued as COSV53312156; called by muse, mutect2
- HRCT1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.119); catalogued as rs750679895, COSV62847082; called by muse, mutect2, varscan2
- HSP90B1 | c.2401G>C p.D801H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs777767051, COSV55356084; called by muse, mutect2, varscan2
- HSPG2 | c.1130C>G p.S377C | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV65930431; called by muse, mutect2, varscan2
- HSPH1 | c.2320C>T p.L774F | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as COSV60711970; called by muse, mutect2, varscan2
- IFT122 | c.2371G>A p.D791N (on ENST00000348417 / NM_052989.3; = p.D732N on NM_018262.4) | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV99959461; called by muse, mutect2
- IHO1 | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 33/286 reads (12%) | catalogued as COSV99606271; called by muse, mutect2, varscan2
- IKZF2 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1271090843, COSV59578675, COSV59580017; called by muse, mutect2, varscan2
- IMPG2 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV51975926; called by muse, varscan2
- IMPG2 | c.388G>C p.G130R | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV51980108; called by muse, varscan2
- INO80B | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 10/101 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV51970000, COSV99270477; called by muse, mutect2, varscan2
- INTS2 | c.731G>A p.R244K | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.632); catalogued as COSV52153904; called by muse, mutect2, varscan2
- INTS6 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.756); catalogued as COSV60878852; called by muse, mutect2, varscan2
- IQCB1 | c.1629G>T p.R543S | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as COSV60438033; called by muse, mutect2, varscan2
- ISCA2 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53143650; called by muse, mutect2, varscan2
- ITGA11 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59878697; called by muse, mutect2, varscan2
- ITGAV | c.1463A>C p.N488T | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as COSV53714205; called by muse, mutect2, varscan2
- ITPRIPL2 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1408005559, COSV67347781; called by muse, mutect2, varscan2
- JMJD1C | c.4127C>T p.S1376L | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV59516125; called by muse, mutect2, varscan2
- JMJD1C | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.341); catalogued as COSV67863261; called by muse, mutect2, varscan2
- KALRN | c.3445A>G p.T1149A | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.358); catalogued as COSV53768643; called by muse, mutect2, varscan2
- KAT6B | c.751T>G p.F251V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54749434; called by muse, mutect2, varscan2
- KAZALD1 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.728); catalogued as rs1050193986, COSV100930599, COSV64630124; called by muse, mutect2
- KBTBD2 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as COSV58363402, COSV58363760; called by muse, mutect2, varscan2
- KCNV1 | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV52086753, COSV52088893; called by muse, mutect2, varscan2
- KDM1A | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV63088652; called by muse, mutect2, varscan2
- KDM1A | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV63087863; called by muse, mutect2, varscan2
- KDM5C | c.3441C>T p.I1147= | Splice Region (SNP) | VAF 7/27 reads (26%) | catalogued as rs45442400, COSV100949280; ClinVar: benign / likely benign; called by muse, mutect2
- KHDRBS1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV56982430; called by muse, mutect2, varscan2
- KIAA0319L | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as COSV57846896; called by muse, mutect2, varscan2
- KIF17 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV56119315; called by muse, mutect2, varscan2
- KIF19 | c.2371C>T p.R791W | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs767089420, COSV63428839; called by muse, mutect2, varscan2
- KIF1B | c.1661G>A p.G554E (on ENST00000377086 / NM_001365952.1; = p.G508E on NM_015074.3) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55810517; called by muse, mutect2, varscan2
- KIF20A | c.1082T>C p.V361A | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.258); catalogued as COSV50154184; called by muse, mutect2, varscan2
- KIF21A | c.346C>G p.R116G | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62773112, COSV62777973; called by muse, mutect2, varscan2
- KIF22 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1342207187, COSV50715830; called by muse, mutect2, varscan2
- KIF26B | c.2091A>C p.K697N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100832703; called by muse, varscan2
- KIFC2 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV56761540; called by muse, mutect2, varscan2
- KLHDC3 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.734); catalogued as COSV55064467; called by muse, mutect2, varscan2
- KLRG2 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100572528; called by muse, mutect2
- KMT2A | c.7064C>T p.S2355F | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); catalogued as COSV63287470; called by muse, mutect2, varscan2
- KMT2D | c.10169G>T p.C3390F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as rs1196665028, COSV56452856; called by muse, mutect2, varscan2
- KNDC1 | c.4052C>G p.S1351C | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV58839847; called by muse, varscan2
- KRT16 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs751388606, COSV56968500; called by muse, mutect2, varscan2
- KRT17 | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1355547921, COSV60860804, COSV60861067; called by muse, mutect2, varscan2
- KRT33A | c.1137C>G p.D379E | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99144911; called by muse, mutect2
- KRT33B | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52441235; called by muse, mutect2, varscan2
- KRT38 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as COSV55846419; called by muse, mutect2, varscan2
- KRT75 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as rs1200507317, COSV52873419; called by muse, mutect2, varscan2
- KRT80 | c.1100A>G p.Q367R | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1296933681, COSV57549937; called by muse, mutect2, varscan2
- KRT80 | c.242A>C p.N81T | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57549955; called by muse, mutect2, varscan2
- KRTAP10-5 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.096); catalogued as rs781937002, COSV59966964; called by muse, mutect2, varscan2
- LAMC1 | c.2888A>T p.Q963L | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV51147989; called by muse, mutect2, varscan2
- LARS1 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as rs759545745, COSV99198647; called by muse, mutect2
- LDAH | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV52969515; called by muse, mutect2
- LDHAL6B | c.755G>C p.G252A | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs769974621, COSV55689380; called by muse, mutect2, varscan2
- LEO1 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV55175124; called by muse, mutect2
- LIPI | c.345G>C p.Q115H | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV60712707; called by muse, mutect2, varscan2
- LIX1 | c.356A>G p.E119G | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV57207247; called by muse, mutect2, varscan2
- LLGL2 | c.1101G>C p.Q367H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV51359845; called by muse, mutect2, varscan2
- LMAN2 | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57424869; called by muse, mutect2, varscan2
- LMNA | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs58133342, CM078695, COSV61543231; ClinVar: uncertain significance; called by muse, mutect2
- LOX | c.791G>A p.R264K | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV50238444; called by muse, mutect2, varscan2
- LOXL4 | c.1620G>C p.Q540H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV53257332; called by muse, mutect2, varscan2
- LOXL4 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as COSV53257343; called by muse, mutect2, varscan2
- LRIG3 | c.2621C>T p.S874L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV57865542; called by muse, mutect2, varscan2
- LRP1 | c.3791T>G p.L1264R | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.282); catalogued as COSV54514979; called by muse, mutect2, varscan2
- LRP1 | c.5756C>T p.S1919F | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54514990; called by muse, mutect2, varscan2
- LRP2 | c.11374G>A p.D3792N | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as COSV55558542; called by muse, mutect2, varscan2
- LRP6 | c.3277C>T p.R1093W | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752896710, COSV53789294; called by muse, mutect2
- LRP8 | c.2141C>T p.S714F | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60099307; called by muse, mutect2, varscan2
- LRRC37A2 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as COSV61003387; called by muse, mutect2, varscan2
- LRRCC1 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.655); catalogued as COSV64483850; called by muse, mutect2, varscan2
- LRRTM3 | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.281); catalogued as COSV63667232; called by muse, mutect2, varscan2
- LTBP1 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as rs1449098145, COSV63190055; called by muse, mutect2, varscan2
- LTN1 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV63734074; called by muse, mutect2, varscan2
- LY75 | c.3802A>C p.T1268P | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV55107629; called by muse, mutect2, varscan2
- LY75 | c.3146A>G p.E1049G | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99716602; called by muse, mutect2
- MACF1 | c.11681T>G p.F3894C (on ENST00000372915; = p.F1827C on NM_012090.5) | Missense Mutation (SNP) | VAF 5/104 reads (5%) | catalogued as COSV57127401; called by muse, mutect2
- MADD | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs948105805, COSV60625442; called by muse, mutect2
- MAP1B | c.5989G>T p.G1997C | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.533); catalogued as COSV57100856; called by muse, mutect2, varscan2
- MAP1LC3B | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.576); catalogued as COSV99220779; called by muse, mutect2, varscan2
- MAPK14 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100004786; called by muse, mutect2
- MAPK6 | c.1906A>G p.K636E | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV55930491; called by muse, mutect2, varscan2
- MAPRE2 | c.634G>C p.A212P | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV55819686; called by muse, mutect2, varscan2
- MAST1 | c.1167C>G p.Y389* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV52245937, COSV99263129; called by muse, mutect2, varscan2
- MBNL3 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63731102; called by muse, mutect2, varscan2
- MCCC2 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.86); catalogued as COSV60153099, COSV60155009; called by muse, mutect2, varscan2
- MCM9 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60163382, COSV60164452; called by muse, mutect2, varscan2
- MDC1 | c.2324A>G p.Y775C | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV64525072; called by muse, mutect2
- MDM1 | c.19-1G>A p.X7_splice | Splice Site (SNP) | VAF 40/191 reads (21%) | catalogued as COSV57447116; called by muse, mutect2, varscan2
- MED12 | c.1502A>G p.D501G | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV61343689; called by muse, mutect2, varscan2
- MELK | c.1517T>C p.V506A | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs1426295174, COSV53199758; called by muse, mutect2
- MELK | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as rs2068826, COSV53199766; called by muse, mutect2
- MEPE | c.893C>G p.T298R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV63073178; called by muse, mutect2, varscan2
- METTL18 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as rs1465329772, COSV53679779; called by muse, mutect2, varscan2
- MIF4GD | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 37/212 reads (17%) | catalogued as rs764002197, COSV55453787, COSV99821632; called by muse, mutect2, varscan2
- MIXL1 | c.447C>G p.F149L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.091); catalogued as COSV64729204; called by muse, mutect2, varscan2
- MIXL1 | c.647C>G p.S216* | Nonsense Mutation (SNP) | VAF 18/145 reads (12%) | catalogued as COSV100830817; called by muse, mutect2, varscan2
- MROH2B | c.3325G>A p.E1109K | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.137); catalogued as rs1427712030, COSV101270924, COSV68181885, COSV68186148; called by muse, mutect2, varscan2
- MRPS18C | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.136); catalogued as COSV55025730; called by muse, mutect2, varscan2
- MRPS31 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); catalogued as COSV60267283; called by muse, mutect2, varscan2
- MTERF2 | c.1034A>C p.K345T | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV53527842; called by muse, mutect2
- MTMR14 | c.179G>A p.R60K | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs777695208, COSV56005592; called by muse, mutect2, varscan2
- MTMR6 | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 6/69 reads (9%) | catalogued as COSV101110798; called by muse, mutect2
- MUC16 | c.23675C>T p.S7892F | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as COSV67474101; called by muse, mutect2, varscan2
- MUC16 | c.10014G>C p.K3338N | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); catalogued as COSV67474114; called by muse, mutect2
- MUC16 | c.1037C>T p.T346I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV67474122; called by muse, mutect2, varscan2
- MUC2 | c.2339G>A p.R780Q | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs771839541; called by muse, mutect2
- MYCBP2 | c.5687A>G p.D1896G (on ENST00000357337; = p.D1934G on NM_015057.5) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); catalogued as COSV62024144; called by muse, mutect2, varscan2
- MYH10 | c.3550G>A p.E1184K | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV52603073; called by muse, mutect2, varscan2
- MYLK2 | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV65659245; called by muse, mutect2, varscan2
- MYLK4 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV51143394; called by muse, mutect2
- MYO3A | c.74A>T p.E25V | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56335395, COSV56338667; called by muse, mutect2
- MYO9A | c.6571C>T p.H2191Y | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61852832; called by muse, mutect2, varscan2
- MYT1L | c.1386G>A p.M462I | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV67722934; called by muse, mutect2, varscan2
- N4BP3 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs141941070; called by mutect2, varscan2
- NAMPT | c.947A>G p.N316S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV55995455; called by muse, mutect2, varscan2
- NAT9 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.092); catalogued as COSV52853706; called by muse, mutect2, varscan2
- NCEH1 | c.671G>A p.R224K (on ENST00000538775; = p.R184K on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56432920, COSV56435265; called by muse, mutect2, varscan2
- NCOA3 | c.3421C>T p.Q1141* | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as COSV100507701; called by muse, mutect2
- NDUFA8 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs1422703832, COSV65649087; called by muse, mutect2, varscan2
- NEB | c.4981G>T p.D1661Y | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51426960; called by muse, mutect2, varscan2
- NEFH | c.1336G>C p.V446L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100151600, COSV60218077; called by muse, mutect2, varscan2
- NFE2L3 | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV50230495; called by muse, mutect2, varscan2
- NID1 | c.2105G>C p.R702P | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as rs149309893, COSV51622376; called by mutect2, varscan2
- NKAIN4 | c.244T>G p.F82V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV64786058; called by muse, mutect2
- NOP58 | c.453G>T p.L151F | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV51897173; called by muse, mutect2, varscan2
- NOP9 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51866379; called by muse, mutect2, varscan2
- NOTCH2 | c.5338G>A p.E1780K | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as COSV56690876; called by muse, mutect2, varscan2
- NPLOC4 | c.1448A>G p.Q483R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV58616819; called by muse, mutect2, varscan2
- NUDT16 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.316); catalogued as rs1378522401, COSV63248103; called by muse, mutect2, varscan2
- NUP160 | c.1749G>C p.E583D | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as COSV65854745; called by muse, mutect2, varscan2
- NUP214 | c.3395C>T p.P1132L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); catalogued as rs1311502646, COSV63910444; called by muse, mutect2, varscan2
- NUTM1 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100149227, COSV59217368; called by muse, mutect2, varscan2
- OBSL1 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.282); catalogued as COSV54722013; called by muse, mutect2, varscan2
- OGDH | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.033); catalogued as COSV56052118; called by muse, mutect2, varscan2
- OGFRL1 | c.1025T>C p.M342T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs772497490, COSV64972106; called by muse, mutect2, varscan2
- OMG | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.203); catalogued as COSV55987988, COSV55988230; called by muse, mutect2, varscan2
- OR10J5 | c.767T>C p.I256T | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.344); catalogued as rs1364136928, COSV58386469; called by muse, mutect2, varscan2
- OR4X1 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60723168; called by muse, mutect2, varscan2
- OR51F2 | c.40T>G p.F14V | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59065103; called by muse, mutect2, varscan2
- OR52E4 | c.817A>G p.I273V | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV57625198; called by muse, mutect2, varscan2
- OR5F1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV53546990, COSV53548257; called by muse, mutect2, varscan2
- OR6A2 | c.188T>G p.F63C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV60265171; called by muse, mutect2, varscan2
- OR6N2 | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV59411850; called by muse, mutect2
- OSBPL6 | c.1679C>G p.P560R | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV51920823, COSV51926147; called by muse, mutect2, varscan2
- OSM | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV53161555; called by muse, mutect2, varscan2
- OSMR | c.2470A>G p.R824G | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV57086547; called by muse, mutect2
- OTOA | c.2422C>T p.Q808* (on ENST00000286149; = p.Q794* on NM_144672.4) | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | catalogued as COSV99624894; called by muse, mutect2, varscan2
- P2RX7 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55855905; called by muse, mutect2, varscan2
- P3H1 | c.943G>C p.G315R | Missense Mutation (SNP) | VAF 259/366 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs753051532, COSV52532723; called by muse, mutect2, varscan2
- P4HB | c.146-2A>T p.X49_splice | Splice Site (SNP) | VAF 14/89 reads (16%) | catalogued as COSV58941927; called by muse, mutect2, varscan2
- PAAF1 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs374237947, COSV60154534, COSV60155919; called by muse, varscan2
- PADI1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV64938678; called by muse, mutect2, varscan2
- PAF1 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.057); catalogued as COSV55394752; called by muse, mutect2, varscan2
- PAN3 | c.2063T>A p.I688K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.34); catalogued as COSV56704343; called by muse, mutect2, varscan2
- PAPPA | c.1550T>C p.F517S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60285879; called by muse, mutect2, varscan2
- PAQR8 | c.737G>C p.W246S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.065); catalogued as COSV62442864; called by muse, mutect2, varscan2
- PARP14 | c.982C>G p.L328V | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.824); catalogued as COSV71734879; called by muse, mutect2
- PAXX | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV65406665; called by muse, mutect2
- PCDH15 | c.5224G>A p.E1742K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.01); catalogued as COSV64703061; called by mutect2, varscan2
- PCF11 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV53529616; called by muse, mutect2, varscan2
- PCLO | c.8960T>A p.I2987N | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.382); catalogued as COSV61642465; called by muse, mutect2, varscan2
- PDE3B | c.2272C>T p.P758S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56383391; called by muse, mutect2, varscan2
- PDIA6 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV55351424; called by muse, mutect2, varscan2
- PDP2 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV61240764; called by muse, mutect2, varscan2
- PDXDC1 | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV57908201; called by muse, mutect2, varscan2
- PEX5L | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV55846851, COSV55848476; called by muse, mutect2, varscan2
- PEX5L | c.1142T>C p.V381A | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.191); catalogued as COSV55848498; called by muse, mutect2, varscan2
- PGBD4 | c.219G>A p.M73I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV56628187; called by muse, mutect2, varscan2
- PHACTR3 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV100732740; called by muse, mutect2
- PHF11 | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV51635116; called by muse, mutect2, varscan2
- PHLDB3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52670200; called by muse, mutect2, varscan2
- PHYHD1 | c.213G>C p.L71F | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58281228; called by muse, mutect2, varscan2
- PHYHIPL | c.246C>G p.H82Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs147685227, COSV65848900; called by muse, mutect2, varscan2
- PIK3C2B | c.2732C>T p.S911L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV100916157; called by muse, mutect2
- PIK3C2G | c.260A>T p.N87I | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.748); catalogued as COSV56813920; called by muse, mutect2
- PIKFYVE | c.2599C>T p.Q867* | Nonsense Mutation (SNP) | VAF 7/79 reads (9%) | catalogued as COSV100010933, COSV52242799; called by muse, mutect2
- PIKFYVE | c.2600A>T p.Q867L | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52243251; called by muse, mutect2
- PIM2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV50234244, COSV99332158; called by muse, mutect2, varscan2
- PLA2R1 | c.1609G>C p.D537H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV51778585, COSV51780843; called by muse, mutect2, varscan2
- PLB1 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs776563538, COSV59828267; called by muse, mutect2, varscan2
- PLCZ1 | c.1675C>G p.Q559E | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as rs1334112989, COSV56854194; called by muse, mutect2
- PLEKHG4 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as COSV64611906, COSV64613177; called by muse, mutect2, varscan2
- PLEKHG4 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV64613181; called by muse, mutect2, varscan2
- PLEKHM1 | c.3059+1G>A p.X1020_splice | Splice Site (SNP) | VAF 6/31 reads (19%) | catalogued as COSV69599081; called by muse, mutect2, varscan2
- PLXND1 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100139942; called by muse, mutect2
- PMS2 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.156); catalogued as COSV56149941; called by muse, mutect2, varscan2
- PNRC1 | c.610C>T p.H204Y | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as rs759962048, COSV60139878; called by muse, mutect2, varscan2
- PODXL2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100686106; called by muse, mutect2
- POLA2 | c.1579G>T p.V527F | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.079); catalogued as COSV55484019; called by muse, varscan2
- POLDIP3 | c.521A>C p.N174T | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV52809363; called by muse, mutect2, varscan2
- POLE | c.5350G>A p.E1784K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs1555222266, COSV57682874; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLH | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs760303655, COSV64779883; called by muse, mutect2, varscan2
- POU3F2 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as COSV60408811; called by muse, mutect2, varscan2
- PPP1R26 | c.269A>G p.H90R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as COSV63355968; called by muse, mutect2, varscan2
- PPP4R1 | c.2752C>T p.Q918* (on ENST00000400556 / NM_001042388.3; = p.Q901* on NM_005134.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as COSV53281215; called by muse, mutect2
- PPP4R2 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV55596228; called by muse, mutect2, varscan2
- PPP4R3A | c.2059G>A p.E687K (on ENST00000554943 / NM_001366432.1; = p.E674K on NM_001284280.1) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV61505257; called by muse, mutect2, varscan2
- PPP4R3A | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as COSV61505262; called by muse, mutect2
- PPP4R4 | c.2312T>G p.I771S | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.037); catalogued as COSV58555584; called by muse, mutect2
- PRDM11 | c.1259C>T p.S420L (on ENST00000530656 / NM_001359633.1; = p.S386L on NM_001256695.1) | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV55439394; called by muse, mutect2, varscan2
- PRICKLE2 | c.1714C>T p.Q572* (on ENST00000295902; = p.Q516* on NM_198859.4) | Nonsense Mutation (SNP) | VAF 15/100 reads (15%) | catalogued as COSV99897507; called by muse, mutect2, varscan2
- PRKDC | c.8644G>A p.A2882T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.143); catalogued as COSV58052523; called by muse, mutect2, varscan2
- PRLHR | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs945808344, COSV53302772; called by muse, mutect2
- PRPF39 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as rs368992834; called by muse, mutect2, varscan2
- PRRC2C | c.6464T>C p.V2155A (on ENST00000367742; = p.V2153A on NM_015172.4) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV58907130; called by muse, mutect2, varscan2
- PRRX1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.221); catalogued as rs1213289345, COSV53415107, COSV53415639; called by muse, mutect2, varscan2
- PSD4 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 37/311 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.059); catalogued as COSV55527536; called by muse, mutect2, varscan2
- PSMA2 | c.565C>T p.H189Y | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55031277, COSV55031424; called by muse, mutect2
- PSMB10 | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV52123860; called by muse, mutect2, varscan2
- PSME4 | c.1171C>G p.Q391E | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776088587, COSV66365735; called by muse, mutect2, varscan2
- PTCHD1 | c.1778A>G p.N593S | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.127); catalogued as COSV65061268; called by muse, mutect2, varscan2
- PTPN1 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65408394; called by muse, mutect2, varscan2
- PTPRD | c.3299C>T p.T1100M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs200684369, COSV61937413, COSV61956848; called by mutect2, varscan2
- PTPRH | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 17/107 reads (16%) | catalogued as rs200281532; called by muse, mutect2, varscan2
- PXDN | c.3592C>T p.R1198W | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs570640127, COSV53237614, COSV99412394; called by muse, mutect2
- RAB6D | c.335G>A p.R112K | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.213); catalogued as rs1413610668, COSV72151661; called by muse, varscan2
- RAD51 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV51111510; called by muse, mutect2, varscan2
- RANBP2 | c.167A>G p.Q56R | Missense Mutation (SNP) | VAF 41/372 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs761466894, COSV99312442; called by muse, mutect2, varscan2
- RANBP2 | c.6506G>A p.R2169K | Missense Mutation (SNP) | VAF 22/361 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99312443; called by muse, mutect2
- RAPGEF1 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV64700141; called by muse, mutect2, varscan2
- RASA2 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV53941659; called by muse, mutect2, varscan2
- RASAL2 | c.2558G>C p.R853T | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100862688; called by muse, mutect2
- RCAN2 | c.224A>G p.Q75R | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV57817089; called by muse, mutect2
- RDM1 | c.224G>C p.R75T | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1490584262; called by muse, mutect2, varscan2
- RELN | c.6385G>A p.G2129S | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as rs1228682428, COSV59010164; ClinVar: uncertain significance; called by muse, mutect2
- RFC5 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV57477903; called by muse, mutect2, varscan2
- RFT1 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV56249212; called by muse, mutect2, varscan2
- RFX3 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV56518068; called by muse, mutect2
- RIN2 | c.1361C>G p.P454R (on ENST00000255006 / NM_001242581.1; = p.P405R on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.462); catalogued as rs1365504444, COSV99657317; called by muse, mutect2
- RIN2 | c.2593G>A p.E865K (on ENST00000255006 / NM_001242581.1; = p.E816K on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV54789757; called by muse, mutect2
- RMND5A | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV52154196, COSV99373959; called by muse, mutect2, varscan2
- RNF123 | c.1619G>A p.S540N | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV59688502; called by muse, mutect2
- RNF19A | c.2354C>G p.S785C | Missense Mutation (SNP) | VAF 130/260 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.237); catalogued as COSV61993630; called by muse, mutect2, varscan2
- RNF213 | c.2128G>A p.D710N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as COSV100173516, COSV60625390; called by mutect2, varscan2
- RNF25 | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV99829052; called by muse, mutect2, varscan2
- ROCK1 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as COSV67696647, COSV67697336; called by muse, mutect2
- RPS6KA2 | c.1936A>G p.K646E | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV55822728; called by muse, mutect2
- RPS6KC1 | c.451T>A p.F151I | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV65300457; called by muse, mutect2
- RTL5 | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as COSV101030176; called by muse, mutect2, varscan2
- RTN3 | c.3054-1G>A p.X1018_splice (on ENST00000377819 / NM_001265589.2; = p.X222_splice on NM_006054.4) | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100380222; called by muse, mutect2
- RUNX1 | c.196G>A p.D66N (on ENST00000344691 / NM_001001890.3; = p.D93N on NM_001754.5) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs757412228, COSV100277689, COSV55886033; called by muse, mutect2
- SAA4 | c.92-1G>A p.X31_splice | Splice Site (SNP) | VAF 20/131 reads (15%) | catalogued as COSV53448453; called by muse, mutect2, varscan2
- SASH1 | c.571C>G p.Q191E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV66562720; called by muse, mutect2, varscan2
- SBF2 | c.4888G>A p.D1630N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99814639; called by muse, varscan2
- SCAF4 | c.2416G>A p.G806S | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV54588569; called by muse, mutect2, varscan2
- SCAP | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV55562429; called by muse, mutect2, varscan2
- SCN2A | c.4180C>T p.Q1394* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as rs1553593810, COSV51845670; called by muse, mutect2, varscan2
- SCN7A | c.2755A>C p.I919L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as COSV69272533; called by muse, mutect2, varscan2
- SDC2 | c.362T>C p.M121T | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV56228492; called by muse, mutect2
- SDK1 | c.3385G>A p.D1129N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as COSV67374138; called by muse, mutect2, varscan2
- SEC24D | c.2314C>T p.Q772* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as rs1422236800, COSV99756270; called by muse, mutect2, varscan2
- SEC61A2 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV53652890; called by muse, mutect2
- SELE | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60976338; called by muse, mutect2, varscan2
- SELENOP | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV62792914; called by muse, mutect2, varscan2
- SESTD1 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 34/269 reads (13%) | catalogued as COSV100090610, COSV58932183; called by muse, mutect2, varscan2
- SETD4 | c.1087C>T p.L363F | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs889269140, COSV59772551; called by muse, mutect2, varscan2
- SETD5 | c.2825C>T p.S942F | Missense Mutation (SNP) | VAF 84/195 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.085); catalogued as COSV56712953; called by muse, mutect2, varscan2
- SETX | c.8021G>A p.R2674K | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.368); catalogued as COSV56387624; called by muse, mutect2, varscan2
- SFI1 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs757364424, COSV66291274; called by muse, mutect2, varscan2
- SH2D2A | c.25T>C p.C9R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.289); catalogued as rs754078455, COSV63884960; called by muse, mutect2, varscan2
- SH2D7 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1271721566, COSV51948887; called by muse, mutect2, varscan2
- SHCBP1L | c.1742A>G p.N581S | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1230175325, COSV62355424; called by muse, mutect2, varscan2
- SHCBP1L | c.914A>C p.K305T | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV62355432; called by muse, mutect2, varscan2
- SHROOM4 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99173685; called by muse, mutect2
- SIRPD | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs774848088, COSV67546793; called by muse, mutect2, varscan2
- SKI | c.275T>A p.M92K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs1405859575, COSV101049447; called by muse, mutect2
- SKIV2L | c.839A>T p.Q280L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV64812343; called by muse, mutect2, varscan2
- SKIV2L | c.2771A>G p.D924G | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV61714046; called by muse, mutect2, varscan2
- SLC12A5 | c.1441G>C p.E481Q (on ENST00000454036 / NM_001134771.2; = p.E458Q on NM_020708.5) | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as COSV54795619, COSV99716321; called by muse, mutect2, varscan2
- SLC17A5 | c.817C>G p.Q273E | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV63287686; called by muse, mutect2, varscan2
- SLC18A1 | c.395T>C p.L132S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1483203486, COSV52348803, COSV99368418; called by muse, mutect2, varscan2
- SLC1A4 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.222); catalogued as COSV52234880; called by muse, mutect2, varscan2
- SLC2A7 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV68901924; called by muse, mutect2, varscan2
- SLC39A12 | c.870T>G p.N290K | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV66199379; called by muse, mutect2, varscan2
- SLC39A2 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.76); catalogued as COSV53869919; called by muse, mutect2, varscan2
- SLC44A2 | c.1234-1G>A p.X412_splice | Splice Site (SNP) | VAF 4/74 reads (5%) | catalogued as COSV100213271; called by muse, mutect2
- SLC4A1 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52260981; called by muse, mutect2, varscan2
- SLC5A8 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV73310788; called by muse, mutect2, varscan2
- SLC7A7 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.085); catalogued as rs763832201, COSV53541179; called by muse, mutect2, varscan2
- SLC9C1 | c.874C>T p.L292F | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as COSV59889376; called by muse, mutect2, varscan2
- SLCO2A1 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV60486679, COSV60487751; called by muse, mutect2, varscan2
- SLITRK4 | c.2395C>T p.H799Y | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); catalogued as rs1278152007, COSV62024603; called by muse, mutect2, varscan2
- SMG8 | c.2414G>A p.R805K | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV56284609, COSV56285867; called by muse, mutect2, varscan2
- SMPDL3B | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV65870905; called by muse, mutect2, varscan2
- SMPDL3B | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1248463187, COSV65855019; called by muse, mutect2
- SNAI2 | c.649C>T p.H217Y | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV99194962, COSV99194972; called by muse, mutect2
- SNX27 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV64326703; called by muse, mutect2, varscan2
- SNX7 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV100069159, COSV60272096; called by muse, mutect2
- SOX5 | c.1874A>T p.Y625F | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58634172; called by muse, varscan2
- SP1 | c.176C>T p.S59F (on ENST00000327443 / NM_138473.3; = p.S52F on NM_003109.1) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59402369, COSV59403652; called by muse, mutect2, varscan2
- SPAG17 | c.2009G>A p.R670K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV60456255; called by muse, mutect2, varscan2
- SPAG17 | c.1956G>A p.M652I | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV60456688; called by muse, mutect2
- SPAG5 | c.2885-1G>C p.X962_splice | Splice Site (SNP) | VAF 10/98 reads (10%) | catalogued as COSV56886565; called by muse, mutect2, varscan2
- SPATA31E1 | c.3230C>T p.S1077L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.412); catalogued as COSV57792754; called by muse, mutect2, varscan2
- SPDYA | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.321); catalogued as rs1469358572, COSV61856290; called by muse, mutect2, varscan2
- SPIDR | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.191); catalogued as COSV52380258; called by muse, mutect2, varscan2
- SPN | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 13/118 reads (11%) | catalogued as COSV100788822; called by muse, mutect2, varscan2
- SPRED2 | c.1054C>T p.H352Y | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV62693516; called by muse, mutect2, varscan2
- SPTBN1 | c.6934G>A p.E2312K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs540132022, COSV63340562; called by muse, mutect2, varscan2
- SPTLC2 | c.325A>G p.K109E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV53640836; called by muse, mutect2, varscan2
- SPX | c.241A>T p.I81F | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV57021073; called by muse, mutect2, varscan2
- SRBD1 | c.2590G>C p.E864Q | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV55400398; called by muse, mutect2, varscan2
- SREK1IP1 | c.89A>G p.N30S | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs754601766, COSV72486294; called by muse, mutect2, varscan2
- SRRT | c.50G>A p.R17K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV52342204; called by muse, mutect2, varscan2
- SSH3 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.292); catalogued as rs769558402, COSV57385198; called by muse, mutect2, varscan2
- SSH3 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.262); catalogued as COSV57384410, COSV57385208; called by muse, mutect2, varscan2
- STAG3 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV57931526; called by muse, mutect2, varscan2
- STEAP2 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55291763; called by muse, mutect2, varscan2
- STEAP3 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV61529503; called by muse, mutect2, varscan2
- STIL | c.940T>C p.Y314H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54551080; called by muse, mutect2, varscan2
- STK36 | c.927G>T p.M309I | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as rs1324774675, COSV55327523; called by muse, mutect2, varscan2
- SWSAP1 | c.523C>T p.P175S (on ENST00000312423; = p.P196S on NM_175871.4) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as COSV55800665, COSV99710079; called by muse, mutect2, varscan2
- SYBU | c.1330G>A p.E444K (on ENST00000276646 / NM_001099754.2; = p.E443K on NM_017786.6) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.443); catalogued as COSV52619582; called by muse, mutect2, varscan2
- SYNE2 | c.14767G>A p.E4923K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.436); catalogued as COSV100648132, COSV59954943; called by muse, mutect2, varscan2
- SYNJ2BP | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.164); catalogued as COSV56445909; called by muse, mutect2, varscan2
- SYT1 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs796766684, COSV99695982; called by muse, mutect2
- SYT8 | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53290033; called by muse, mutect2, varscan2
- TACC2 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV57759320; called by muse, mutect2, varscan2
- TANC1 | c.2830C>T p.H944Y | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs374498239; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TASOR2 | c.4427C>T p.S1476F | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV60168011; called by muse, mutect2, varscan2
- TAX1BP1 | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as COSV55292674; called by muse, mutect2, varscan2
- TBC1D14 | c.1963T>C p.F655L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV68986189; called by muse, mutect2, varscan2
- TBC1D9 | c.1231G>C p.E411Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.078); catalogued as COSV101464388, COSV71307689; called by muse, mutect2, varscan2
- TBC1D9B | c.3184G>A p.G1062R (on ENST00000356834 / NM_198868.3; = p.G1045R on NM_015043.4) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs552871928, COSV100783516, COSV62282346; called by muse, mutect2, varscan2
- TCTN2 | c.496C>G p.Q166E | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV57633417; called by muse, mutect2
- TECPR2 | c.2576C>A p.S859* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100850071, COSV63970633; called by muse, mutect2, varscan2
- TENM2 | c.5221G>A p.D1741N (on ENST00000518659 / NM_001122679.2; = p.D1502N on NM_001080428.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV69133329; called by muse, mutect2, varscan2
- TENM4 | c.5927G>A p.R1976K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as COSV53638495; called by muse, mutect2, varscan2
- TET3 | c.4571C>A p.A1524D | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV101327913, COSV69644396; called by muse, mutect2
- TFDP2 | c.466G>A p.D156N (on ENST00000489671 / NM_001178139.2; = p.D95N on NM_006286.5) | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV57708547; called by muse, mutect2
- TG | c.7112G>A p.R2371Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs534667194, COSV55080865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TGFBR3 | c.2223G>A p.M741I | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs1350765482, COSV53026972; called by muse, mutect2
- THBD | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV65702662; called by muse, mutect2, varscan2
- THSD7B | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.908); catalogued as rs1412883962, COSV55700533; called by muse, mutect2, varscan2
- TIGIT | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs1246976269, COSV101048056, COSV67329046; called by muse, mutect2, varscan2
- TIMM23 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1554912865; called by muse, varscan2
- TIPARP | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); catalogued as COSV55814560; called by muse, mutect2, varscan2
- TJP1 | c.4087G>A p.D1363N | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62042506, COSV62042978; called by muse, mutect2, varscan2
- TLK2 | c.2243C>T p.S748L (on ENST00000326270 / NM_001284333.2; = p.S726L on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV58301675; called by muse, mutect2, varscan2
- TLN2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100169268, COSV60891066; called by muse, mutect2, varscan2
- TMC1 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV52777780; called by muse, mutect2, varscan2
- TMED6 | c.664T>G p.F222V | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.526); catalogued as COSV54742658; called by muse, mutect2
- TMEM171 | c.70T>C p.C24R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV55130712; called by muse, mutect2, varscan2
- TMEM79 | c.143G>A p.R48K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.001); catalogued as COSV55295712, COSV55296275; called by muse, mutect2, varscan2
- TMUB2 | c.943G>T p.V315L (on ENST00000538716 / NM_001353177.2; = p.V295L on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.437); catalogued as COSV60229071; called by muse, mutect2, varscan2
- TNFAIP6 | c.281A>C p.Y94S | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54641331; called by muse, mutect2
- TNFRSF1B | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV66164530; called by muse, mutect2, varscan2
- TNN | c.2957A>C p.Q986P | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV53428618, COSV53431176; called by muse, mutect2, varscan2
- TNRC18 | c.2116G>T p.D706Y | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1386413528, COSV68087617; called by muse, mutect2, varscan2
- TNRC6A | c.3908C>T p.S1303L | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV59366428; called by muse, mutect2, varscan2
- TNRC6A | c.4489G>A p.E1497K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as COSV59366435; called by muse, mutect2, varscan2
- TNS3 | c.2528C>T p.S843L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV60793015; called by muse, mutect2, varscan2
- TOE1 | c.1250G>C p.R417T | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1415385963, COSV100516959, COSV59153521; called by muse, mutect2
- TOM1L2 | c.811C>T p.R271C (on ENST00000379504 / NM_001350333.2; = p.R221C on NM_001033551.3) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58886743; called by muse, mutect2, varscan2
- TP53TG5 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.043); catalogued as COSV65577686; called by muse, mutect2, varscan2
- TPI1 | c.746C>T p.S249F (on ENST00000229270; = p.S212F on NM_000365.6) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51290226; called by muse, mutect2, varscan2
- TPTE | c.1490G>A p.W497* (on ENST00000618007 / NM_199261.4; = p.W479* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as rs1231704238; called by muse, mutect2
- TRANK1 | c.7016T>C p.I2339T | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV57153705; called by muse, mutect2
- TRIB2 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.67); catalogued as COSV50226706; called by muse, mutect2, varscan2
- TRIM50 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52721733, COSV99334038; called by muse, mutect2
- TRIM75P | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV72295859; called by muse, mutect2, varscan2
- TRMT44 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV67664173; called by muse, mutect2, varscan2
- TRMT61B | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as COSV60258309; called by muse, mutect2, varscan2
- TRNT1 | c.487G>C p.D163H | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV52408675; called by muse, mutect2, varscan2
- TRPC5 | c.2828C>T p.S943L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV53293701; called by muse, mutect2, varscan2
- TRPS1 | c.1103C>T p.S368F (on ENST00000220888 / NM_001330599.2; = p.S381F on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV55246882; called by muse, mutect2, varscan2
- TRPV2 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.063); catalogued as rs542201846, COSV58428897; called by muse, mutect2, varscan2
- TSPYL4 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV100126860; called by muse, mutect2
- TTC21A | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs796655541, COSV57186142, COSV57189454; called by muse, varscan2
- TTN | c.99761C>T p.S33254L (on ENST00000591111; = p.S25830L on NM_003319.4) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | PolyPhen benign (0.436); catalogued as COSV60135118; called by muse, mutect2, varscan2
- TTN | c.58857T>A p.N19619K (on ENST00000591111; = p.N12195K on NM_003319.4) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | PolyPhen benign (0.337); catalogued as COSV60135143, COSV60241385; called by mutect2, varscan2
- TTN | c.48425T>C p.L16142P (on ENST00000591111; = p.L8718P on NM_003319.4) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | PolyPhen probably damaging (0.999); catalogued as rs777712545, COSV60135232, COSV60268909; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.32635G>A p.E10879K (on ENST00000591111; = p.E9952K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | PolyPhen benign (0.132); catalogued as COSV100617906; called by muse, mutect2
- TUBGCP6 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as rs143957857, COSV99352408; called by muse, mutect2, varscan2
- TUT7 | c.1649C>A p.P550Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV52896441; called by muse, mutect2, varscan2
- TXLNG | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58113119; called by muse, mutect2, varscan2
- TXNDC16 | c.1288A>G p.I430V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs1438486599, COSV55985270; called by muse, mutect2, varscan2
- TYMP | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.01); catalogued as rs1284840530, COSV52689709, COSV99329590; called by muse, mutect2
- UBC | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV60059952; called by muse, mutect2, varscan2
- UBE3B | c.2044C>T p.H682Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV55094803; called by muse, mutect2
- UBQLN2 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV100592747; called by muse, mutect2
- UBXN11 | c.625G>A p.E209K (on ENST00000374221 / NM_183008.2; = p.E176K on NM_145345.2) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.813); catalogued as COSV54625570; called by muse, mutect2, varscan2
- UCHL3 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1381452572, COSV66459835; called by muse, mutect2, varscan2
- UGCG | c.712T>C p.F238L | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV65336043; called by muse, mutect2, varscan2
- UGT2B15 | c.488A>T p.E163V | Missense Mutation (SNP) | VAF 58/240 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV57735077; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2069C>A p.S690Y | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV51956642; called by muse, mutect2, varscan2
- UNC13C | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.164); catalogued as COSV52858434, COSV52886177; called by muse, mutect2, varscan2
- USH2A | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.129); catalogued as rs1348637428, COSV56386448; called by muse, mutect2, varscan2
- USP19 | c.1118G>C p.R373P | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as COSV60046622; called by muse, mutect2, varscan2
- USP25 | c.2249C>T p.S750L | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV53485778; called by muse, mutect2
- USP48 | c.485A>T p.Y162F | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.312); catalogued as COSV57611215; called by muse, mutect2, varscan2
- USP9Y | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV59099679; called by muse, mutect2, varscan2
- USP9Y | c.515T>A p.L172Q | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59099685; called by muse, mutect2, varscan2
- UTRN | c.10154C>T p.S3385F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as COSV100838634; called by muse, mutect2
- UXS1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99308370; called by muse, mutect2, varscan2
- VAV1 | c.2229G>T p.E743D | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV100409158; called by muse, mutect2
- VCAN | c.7961C>G p.S2654* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as COSV99426204; called by muse, mutect2, varscan2
- VPS13B | c.11846C>T p.S3949L | Missense Mutation (SNP) | VAF 31/440 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52554041; called by muse, mutect2
- VPS13C | c.4457A>C p.D1486A (on ENST00000644861 / NM_020821.3; = p.D1443A on NM_017684.5) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV51262057; called by muse, mutect2, varscan2
- VPS13D | c.3160G>A p.D1054N | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV50647544; called by muse, mutect2, varscan2
- VPS50 | c.1921C>G p.Q641E | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as rs1176397204, COSV58508456; called by muse, mutect2, varscan2
- VWA3B | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV68243865; called by muse, varscan2
- VWA3B | c.790C>G p.P264A | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1262228537, COSV68243870; called by muse, varscan2
- WASF2 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV101420790; called by muse, mutect2, varscan2
- WDR36 | c.146G>A p.R49K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV72411253; called by muse, mutect2, varscan2
- WDR72 | c.987G>A p.M329I | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV64748774; called by muse, mutect2, varscan2
- WFDC8 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.828); catalogued as rs371165838; called by muse, mutect2
- WHRN | c.1280A>T p.E427V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV54331680; called by muse, mutect2, varscan2
- XIRP1 | c.4796C>T p.S1599L | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs1457511924, COSV61139138; called by muse, mutect2, varscan2
- XPO1 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV68946405; called by muse, mutect2
- XYLT1 | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs555809214, COSV54479221, COSV54481523; called by mutect2, varscan2
- YAE1 | c.560G>A p.R187K | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV56233148; called by muse, mutect2
- YIPF3 | c.1022A>T p.K341I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.311); catalogued as COSV58305360; called by muse, mutect2, varscan2
- YLPM1 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV53106749; called by muse, mutect2, varscan2
- YTHDC2 | c.2729C>A p.A910E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV50743705; called by muse, mutect2, varscan2
- ZBTB48 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV59840087; called by muse, mutect2, varscan2
- ZC3H13 | c.1448G>A p.R483K | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.97); catalogued as COSV54456467; called by muse, mutect2
- ZC3H6 | c.2393C>G p.S798C | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV59668681; called by muse, mutect2, varscan2
- ZC3H6 | c.2887C>T p.P963S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV59668687; called by muse, mutect2, varscan2
- ZDHHC16 | c.1077G>A p.M359I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV59135968; called by muse, mutect2, varscan2
- ZEB1 | c.893T>C p.V298A | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV58047038; called by muse, mutect2, varscan2
- ZFP36 | c.356C>T p.S119L (on ENST00000594442; = p.S113L on NM_003407.5) | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV50528729; called by muse, mutect2
- ZFP69B | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 98/159 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV64315280; called by muse, mutect2, varscan2
- ZFYVE9 | c.3197G>C p.W1066S | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55095271; called by muse, mutect2, varscan2
- ZIK1 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.276); catalogued as COSV56737460; called by muse, mutect2, varscan2
- ZIK1 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as COSV56737466, COSV56738069; called by muse, mutect2, varscan2
- ZMAT3 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV60993863; called by muse, mutect2, varscan2
- ZNF256 | c.379T>G p.L127V | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs769158501, COSV56597891; called by muse, varscan2
- ZNF302 | c.802C>G p.L268V (on ENST00000627982; = p.L189V on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV71063687; called by muse, mutect2, varscan2
- ZNF34 | c.1261T>C p.C421R | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1435682607, COSV58640004; called by muse, mutect2, varscan2
- ZNF384 | c.1714G>A p.E572K (on ENST00000361959; = p.E511K on NM_133476.5) | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58554251, COSV58555980; called by muse, mutect2, varscan2
- ZNF394 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.151); catalogued as COSV61794005; called by muse, mutect2, varscan2
- ZNF420 | c.1818G>C p.Q606H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV58494605; called by muse, mutect2, varscan2
- ZNF423 | c.2353C>A p.P785T (on ENST00000563137 / NM_001379286.1; = p.P777T on NM_015069.4) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.319); catalogued as COSV52193605; called by mutect2, varscan2
- ZNF430 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as COSV55110544; called by muse, mutect2, varscan2
- ZNF439 | c.195G>C p.Q65H | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.02); catalogued as COSV58309782; called by muse, mutect2, varscan2
- ZNF565 | c.220G>A p.V74M (on ENST00000355114; = p.V34M on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58411094, COSV58411151; called by muse, mutect2, varscan2
- ZNF608 | c.3665T>C p.M1222T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.443); catalogued as COSV60438737; called by muse, mutect2, varscan2
- ZNF614 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 30/182 reads (16%) | catalogued as COSV99571826; called by muse, mutect2, varscan2
- ZNF622 | c.486_501del p.T163Pfs*97 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | catalogued as rs1388957550; called by mutect2, varscan2
- ZNF623 | c.1200G>C p.E400D | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV71697227; called by muse, mutect2, varscan2
- ZNF644 | c.1294C>T p.H432Y | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61348375; called by muse, mutect2, varscan2
- ZNF644 | c.115A>G p.K39E | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV61348380; called by muse, mutect2, varscan2
- ZNF649 | c.46G>C p.D16H | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as COSV61617168; called by muse, mutect2, varscan2
- ZNF750 | c.2149C>T p.R717* | Nonsense Mutation (SNP) | VAF 7/92 reads (8%) | catalogued as COSV99489810; called by muse, mutect2
- ZNF785 | c.1123G>A p.V375M | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as COSV67876394; called by muse, mutect2, varscan2
- ZNF785 | c.338C>G p.S113C | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); catalogued as COSV67876397; called by muse, mutect2, varscan2
- ZNF800 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.091); catalogued as COSV56177310; called by muse, mutect2, varscan2
- ZNF823 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV100362518; called by muse, mutect2
- ZNRF2 | c.566-1G>A p.X189_splice | Splice Site (SNP) | VAF 14/57 reads (25%) | catalogued as COSV100546221; called by muse, mutect2
- ZP2 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54814640, COSV99076906; called by muse, mutect2, varscan2
- ZPBP | c.819A>T p.Q273H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV50426914; called by muse, mutect2, varscan2
- ZXDC | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs1324340925, COSV60447361; called by muse, mutect2
- ASCC3 | c.4677_4690del p.L1559Ffs*19 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- C1orf116 | c.1677_1690del p.S560Efs*3 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel
- CBWD1 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by mutect2, varscan2
- DSP | c.4324C>T p.Q1442* | Nonsense Mutation (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- GSTM2 | c.474_480del p.I159Mfs*21 | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | called by mutect2, pindel
- HAP1 | c.1197del p.M400Cfs*48 (on ENST00000310778 / NM_001367460.1; = p.M400Cfs*44 on NM_177977.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel*, varscan2
- MPO | c.464C>G p.S155* | Nonsense Mutation (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- MTCL1 | c.2807_2811+14del p.X936_splice (on ENST00000306329 / NM_001378206.1; = p.X576_splice on NM_015210.4) | Splice Site (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel
- NOA1 | c.616_631del p.S206Gfs*33 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | called by mutect2, pindel
- PARD3 | c.178_188delinsC p.D60Pfs*6 | Frame Shift Del (DEL) | VAF 38/177 reads (21%) | called by pindel, varscan2*
- PDGFRL | c.380_398del p.Q127Pfs*54 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- PRAMEF19 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 36/828 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); called by muse, mutect2
- PRORP | c.866del p.G289Efs*4 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- RARG | c.944_963del p.A315Gfs*4 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, pindel
- TIAM1 | c.4346_4348del p.R1449del | In Frame Del (DEL) | VAF 11/39 reads (28%) | called by pindel, varscan2
- TNS1 | c.1937dup p.L647Tfs*49 | Frame Shift Ins (INS) | VAF 5/33 reads (15%) | called by pindel, varscan2
- TRIM67 | c.1957dup p.W653Lfs*33 | Frame Shift Ins (INS) | VAF 12/122 reads (10%) | called by mutect2, pindel
- ZWILCH | c.1044dup p.A349Cfs*2 | Frame Shift Ins (INS) | VAF 6/45 reads (13%) | called by mutect2, pindel
- ACLY | c.2091C>T p.F697= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs1555627812, COSV61251181, COSV61252017; called by muse, mutect2, varscan2
- ADCY10 | c.1032C>T p.F344= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV63241601; called by muse, mutect2, varscan2
- ADGRF5 | c.3720C>T p.F1240= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs373573502; called by muse, varscan2
- AHNAK2 | c.7764C>G p.V2588= | Silent (SNP) | VAF 52/264 reads (20%) | catalogued as COSV60916278, COSV60918595; called by muse, mutect2, varscan2
- AHSP | c.222G>A p.L74= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV56529108; called by muse, mutect2
- AKAP4 | c.1956G>A p.E652= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV62074706; called by muse, mutect2, varscan2
- AKAP9 | c.5715G>A p.V1905= (on ENST00000359028; = p.V1873= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV62349376; called by muse, mutect2, varscan2
- AMACR | c.24C>T p.V8= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1219875354, COSV59461431; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.5082A>G p.V1694= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV51850467; called by muse, mutect2, varscan2
- AP1G2 | c.2040G>T p.L680= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV55338779; called by muse, mutect2, varscan2
- ARHGAP33 | c.570C>T p.A190= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs139345874; called by muse, mutect2
- ARID1B | c.5313C>T p.F1771= | Silent (SNP) | VAF 41/281 reads (15%) | catalogued as rs760729997, COSV51648425; called by muse, mutect2, varscan2
- BBS9 | c.2269C>T p.L757= (on ENST00000242067 / NM_001348036.1; = p.L717= on NM_014451.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV54167564, COSV54171808; called by mutect2, varscan2
- BEST3 | c.1197G>A p.L399= | Silent (SNP) | VAF 865/947 reads (91%) | catalogued as COSV58302425; called by muse, mutect2, varscan2
- BMP8A | c.249C>G p.A83= | Silent (SNP) | VAF 21/29 reads (72%) | catalogued as rs543497730, COSV59032083, COSV59033231; called by muse, mutect2, varscan2
- BORCS5 | c.276C>T p.L92= | Silent (SNP) | VAF 9/104 reads (9%) | catalogued as COSV53803181; called by muse, mutect2
- BTBD16 | c.129G>A p.L43= | Silent (SNP) | VAF 52/89 reads (58%) | catalogued as rs1398171423, COSV53263999, COSV53267328; called by muse, mutect2, varscan2
- BUB1 | c.3162G>A p.L1054= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV57061944; called by muse, mutect2, varscan2
- C6 | c.2208T>C p.F736= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as COSV54712036; called by muse, mutect2
- C8B | c.1686G>A p.K562= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV64778140; called by muse, mutect2, varscan2
311 further variants in this file (0 protein-altering or splice-affecting, 291 silent, 20 other) are not listed here.
